Somatic mutation profile of tumor specimen TCGA-KK-A8IC-01A (aliquot TCGA-KK-A8IC-01A-11D-A364-08) from TCGA case TCGA-KK-A8IC, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 54.5 years (19,902 days).
Specimen TCGA-KK-A8IC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b5eecfb-99d7-4e7a-b802-494c4b0444ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A8IC-11A (Solid Tissue Normal), aliquot TCGA-KK-A8IC-11A-12D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/386c2779-17be-4248-8f3e-ff874f447a16

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTBD16 | c.503A>G p.Y168C | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs759045854, COSV99585211; called by muse, mutect2, varscan2
- CDS1 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.693); catalogued as rs761418360, COSV99881022; called by muse, mutect2, varscan2
- CSPP1 | c.2973G>A p.M991I (on ENST00000676605; = p.M950I on NM_024790.6) | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV51589494, COSV99139592; called by muse, mutect2, varscan2
- ERC1 | c.3110G>A p.R1037Q (on ENST00000360905 / NM_178040.4; = p.R1009Q on NM_178039.4) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.689); catalogued as rs758036655, COSV100705684; called by muse, mutect2, varscan2
- IGFN1 | c.3227C>T p.A1076V (on ENST00000295591 / NM_001367841.1; = p.A3533V on NM_001164586.2) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs139600545; called by muse, mutect2, varscan2
- OR2M7 | c.852G>A p.M284I | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV100522657; called by muse, mutect2, varscan2
- RARRES1 | c.386G>C p.R129P | Missense Mutation (SNP) | VAF 49/216 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.642); catalogued as COSV99424155; called by muse, mutect2, varscan2
- RPL7 | c.41T>G p.V14G | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99536451; called by muse, mutect2, varscan2
- TRIM28 | c.1473A>T p.E491D | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV99449367; called by muse, mutect2, varscan2
- TRPM1 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780200870, COSV99856492; called by muse, mutect2, varscan2
- ZFPM2 | c.2213G>A p.R738H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780534224, COSV101023145, COSV65874081; called by muse, mutect2, varscan2
- ZNF521 | c.1576T>C p.S526P | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as rs371804263, COSV100833133; called by muse, mutect2, varscan2
- CAMLG | c.765_785del p.E255_M261del | In Frame Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- SPATA31A1 | c.4010G>T p.C1337F | Missense Mutation (SNP) | VAF 12/287 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2
- MUC16 | c.35868C>T p.T11956= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV101201101; called by muse, mutect2, varscan2
- OR4C11 | c.654C>T p.V218= | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as COSV100155459; called by muse, mutect2, varscan2
- PTPRE | c.498C>T p.P166= | Silent (SNP) | VAF 23/156 reads (15%) | catalogued as rs765958360; called by muse, mutect2, varscan2
- ADGRA1 | c.4-1263G>A | Intron (SNP) | VAF 3/29 reads (10%) | catalogued as COSV101192824; called by muse, mutect2
